Gene-level copy-number profile of tumor specimen ALCH-B3AX-TTP1-A from ALCHEMIST case ALCH-B3AX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.3 years (18,362 days).
Specimen ALCH-B3AX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44fe587e-3028-4f6c-a9e8-c8ae684f8d6e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/dee4bb6e-2cdb-472d-8555-0647f76b5a19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 7,725; copy number 2: 48,840; copy number 3: 1,665; copy number 4: 112; copy number 5: 25; copy number 6: 1; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,555,001–13,555,694, 1 gene: BRWD1P1.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–1): IGKV2D-14.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr3:32,785,646–32,786,116, 1 gene: RPL23AP43.
- chr6:57,919,784–57,930,291, 1 gene: GUSBP4.
- chr7:140,645,829–140,646,126, 1 gene (within-gene range 0–1): RN7SL771P.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr14:100,657,250–100,679,884, 2 genes: LINC00523, AL132711.1.
- chr17:2,688,473–2,749,504, 6 genes (within-gene range 0–1): AC005696.3, MIR6776, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.
- chr17:49,210,411–49,230,787, 2 genes (within-gene range 0–2): ABI3, PHOSPHO1.
- chr19:43,622,368–43,639,850, 1 gene: CADM4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,198,235–74,733,408, 9 genes, copy number 5 (within-gene range 3–5): FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ.
- chr1:90,892,992–91,024,804, 3 genes, copy number 5: PHKA1P1, ZNF644, RPL5P6.
- chr2:242,087,351–242,088,457, 1 gene, copy number 6: AC093642.2.
- chr17:2,054,154–2,063,241, 1 gene, copy number 5 (within-gene range 2–5): HIC1.
- chr19:1,103,926–1,279,244, 11 genes, copy number 5: GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr20:63,953,384–63,956,985, 1 gene, copy number 5 (within-gene range 1–5): UCKL1-AS1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 17 (within-gene range 2–17): GATD3A.

Autosomal genes at a single copy (total copy number 1): 6,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
